Gene-level copy-number profile of tumor specimen TCGA-DQ-5631-01A from TCGA case TCGA-DQ-5631, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G3; Age at diagnosis: 52.5 years (19,172 days).
Specimen TCGA-DQ-5631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.87d8624a-b66b-42aa-83dc-4bcb632856e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DQ-5631-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/494c0370-6051-4e5b-bcd6-6bd395a390ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 216; copy number 2: 19,444; copy number 3: 26,804; copy number 4: 7,692; copy number 5: 2,343; copy number 6: 2,814; copy number 7: 117; copy number 8: 362; copy number 9: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DQ-5631-01A-01D-1869-01): tumor purity 0.58, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 503 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,359,739–86,074,429, 24 genes, copy number 9 (within-gene range 4–9): AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2.
- chr5:58,198–4,041,764, 94 genes, copy number 7 (broad region; genes not listed).
- chr5:4,436,850–20,575,873, 262 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr18:47,390–4,459,458, 100 genes, copy number 8 (broad region; genes not listed).
- chr22:20,707,691–21,081,018, 23 genes, copy number 7 (within-gene range 2–7): PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
